Somatic mutation profile of tumor specimen TARGET-30-PASBPN-01A (aliquot TARGET-30-PASBPN-01A-01D) from TARGET case TARGET-30-PASBPN, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.8 years (279 days).
Specimen TARGET-30-PASBPN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3d23308-1dda-46ad-825a-489e198306ae.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASBPN-10A (Blood Derived Normal), aliquot TARGET-30-PASBPN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5579d780-fa25-47b2-8e81-fa59fa211584

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLHDC7B | c.1437T>C p.S479= (on ENST00000395676; = p.S1120= on NM_138433.5) | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as rs529537700; called by muse, mutect2, varscan2
